Somatic mutation profile of tumor specimen TCGA-AX-A3GB-01A (aliquot TCGA-AX-A3GB-01A-11D-A228-09) from TCGA case TCGA-AX-A3GB, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 73.2 years (26,724 days).
Specimen TCGA-AX-A3GB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1cf6c3b5-92ea-4dc2-a014-8b977c9dfd43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A3GB-10A (Blood Derived Normal), aliquot TCGA-AX-A3GB-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45b32f4f-d62c-438c-8abd-029c1d223668

The open-access MAF lists 86 somatic variants for this specimen: 66 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 18, Nonsense Mutation 7, Intron 2, Splice Region 2, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.95A>T p.D32V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 7/38 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SOX17 | c.1208G>T p.S403I | Missense Mutation (SNP) | VAF 7/38 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52024163; called by muse, mutect2, varscan2
- AASDH | c.653A>C p.N218T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52711262; called by muse, mutect2
- ABCB11 | c.3083C>T p.A1028V | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs1171209104, COSV55585715; called by muse, mutect2
- ACRV1 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as rs891659524, COSV100223614; called by muse, mutect2, varscan2
- ADGRG4 | c.6740A>G p.N2247S | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs755535605, COSV99796355; called by muse, mutect2
- APLNR | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373170562, COSV57241687; called by muse, mutect2, varscan2
- ARSD | c.1307A>G p.D436G | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99472307; called by muse, mutect2, varscan2
- C12orf42 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV100172600; called by muse, mutect2, varscan2
- CACNA1G | c.1375G>A p.G459S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.165); catalogued as COSV100662356; called by muse, mutect2, varscan2
- CORO7 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as rs745958172, COSV52032046; called by mutect2, varscan2
- CPNE8 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as rs750050507, COSV58844155; called by muse, mutect2, varscan2
- CRIM1 | c.1008C>A p.C336* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as COSV54874481, COSV99754191; called by muse, mutect2, varscan2
- DPYSL5 | c.479T>C p.F160S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs772469014, COSV99982691; called by muse, mutect2, varscan2
- EPB41L4B | c.2432C>T p.P811L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs374874684; called by muse, mutect2, varscan2
- EPHB1 | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765851482, COSV67670179; called by muse, mutect2, varscan2
- ESRRB | c.428A>G p.N143S | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.211); catalogued as COSV99835633; called by muse, mutect2, varscan2
- EYA1 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs772877702, COSV100380097; called by muse, mutect2, varscan2
- FAM50A | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99341164; called by muse, mutect2, varscan2
- GABBR1 | c.1165G>A p.V389I | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs1454588749, COSV100589958; called by muse, mutect2, varscan2
- GUCA1A | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50004885; called by muse, mutect2, varscan2
- HECTD1 | c.3337C>T p.R1113C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs374023878; called by muse, mutect2, varscan2
- HERC2 | c.12341C>T p.T4114I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV99876102; called by muse, mutect2, varscan2
- HSPG2 | c.3922C>T p.R1308W | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs758559575, COSV101021049; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGSF1 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs200514048, COSV100812256; called by muse, mutect2
- KATNAL1 | c.618T>G p.H206Q | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV101017119; called by muse, mutect2
- KCNC2 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as rs1191875389, COSV100128323; called by muse, mutect2
- KRT5 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs60720877, CM062803; called by muse, mutect2, varscan2
- KRTAP10-11 | c.692G>A p.C231Y | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs782389438, COSV100555022; called by muse, mutect2, varscan2
- MED12 | c.1583T>A p.L528H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100379454; called by muse, mutect2, varscan2
- MRC1 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as rs1018321923; called by muse, mutect2, varscan2
- MTUS2 | c.3558A>C p.E1186D (on ENST00000612955 / NM_001366650.1; = p.E165D on NM_015233.6) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.501); catalogued as COSV100040876; called by muse, mutect2, varscan2
- NCS1 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100970003; called by muse, mutect2, varscan2
- NUP160 | c.1681A>T p.K561* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | catalogued as COSV101021605; called by muse, mutect2, varscan2
- OGA | c.1194C>T p.S398= | Splice Region (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100761940; called by muse, mutect2, varscan2
- OR52A5 | c.421C>A p.Q141K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0.03); catalogued as COSV100263529, COSV99048632; called by muse, mutect2, varscan2
- PFKFB1 | c.1171A>T p.I391F | Missense Mutation (SNP) | VAF 8/41 reads (20%) | PolyPhen probably damaging (0.978); catalogued as COSV100895826; called by muse, mutect2, varscan2
- PHEX | c.2149G>T p.V717F | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as CD992543, COSV101039945; called by muse, mutect2
- PIK3CD | c.2324G>C p.G775A | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.626); catalogued as COSV100740412; called by muse, mutect2, varscan2
- PLA2G15 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 26/82 reads (32%) | catalogued as rs779032571, COSV99547338; called by muse, mutect2, varscan2
- PNKD | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.547); catalogued as rs768336954, COSV99282613; called by muse, mutect2, varscan2
- PRR14L | c.6141A>G p.I2047M | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100392668; called by muse, mutect2
- RFX4 | c.512G>A p.R171Q (on ENST00000392842 / NM_213594.3; = p.R77Q on NM_032491.6) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.921); catalogued as rs778949159, COSV99986225; called by muse, mutect2, varscan2
- SI | c.5247G>A p.Q1749= | Splice Region (SNP) | VAF 7/58 reads (12%) | catalogued as COSV100016743, COSV52308094; called by muse, mutect2, varscan2
- SKOR1 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV100408559; called by muse, mutect2, varscan2
- SLC26A11 | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63279993; called by muse, mutect2, varscan2
- STRBP | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as COSV62119392; called by muse, mutect2, varscan2
- SYT12 | c.1150G>A p.V384M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as rs1444450312, COSV101210996; called by muse, mutect2, varscan2
- TES | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.679); catalogued as rs747109325, COSV64042208; called by muse, mutect2, varscan2
- TFAP2A | c.356A>T p.Q119L (on ENST00000482890; = p.Q111L on NM_001032280.3) | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.885); catalogued as COSV100117128; called by muse, mutect2, varscan2
- TGM1 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs775030916, COSV52861924; called by muse, mutect2, varscan2
- TMEM184B | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs370041072; called by muse, mutect2, varscan2
- TNS1 | c.1627G>A p.G543S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs1020212472, COSV99409812; called by muse, mutect2, varscan2
- TUBA3C | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.353); catalogued as rs1191887593, COSV101262746, COSV67140213; called by muse, mutect2, varscan2
- UGT2B15 | c.806G>C p.R269P | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100592420; called by muse, mutect2, varscan2
- USP47 | c.3028G>T p.E1010* (on ENST00000399455 / NM_001372095.1; = p.E922* on NM_017944.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100359875; called by mutect2, varscan2
- VPS37C | c.644T>A p.V215E | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as rs751128579, COSV100075283; called by muse, mutect2, varscan2
- VPS53 | c.1912G>A p.V638I (on ENST00000571805 / NM_001366253.2; = p.V609I on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.061); catalogued as rs1354310770, COSV99346553; called by muse, mutect2, varscan2
- ZBED8 | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as rs199822370, COSV68824785; called by muse, mutect2, varscan2
- ZMYM2 | c.1679C>T p.P560L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (0.951); catalogued as COSV101244014; called by muse, mutect2
- ZNF521 | c.2659G>A p.G887S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.756); catalogued as rs779117190, COSV100833105; called by muse, mutect2, varscan2
- ZNF599 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs754417637, COSV61396603; called by mutect2, varscan2
- BRD4 | c.2103dup p.E702Rfs*7 | Frame Shift Ins (INS) | VAF 5/32 reads (16%) | called by mutect2, pindel, varscan2
- PCDHGB5 | c.2233C>A p.P745T | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTEN | c.961del p.T321Qfs*23 | Frame Shift Del (DEL) | VAF 23/56 reads (41%) | called by mutect2, pindel, varscan2
- ANGEL2 | c.1383C>T p.D461= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs368233542, COSV64738666; called by muse, mutect2, varscan2
- ATP23 | c.39G>C p.A13= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV100274509; called by muse, mutect2, varscan2
- CPXM2 | c.2178C>T p.I726= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV99583068; called by muse, mutect2, varscan2
- DLEC1 | c.1821T>A p.P607= | Silent (SNP) | VAF 5/80 reads (6%) | catalogued as COSV100343190; called by muse, mutect2
- ERVW-1 | c.18T>C p.H6= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV101423863; called by muse, mutect2, varscan2
- GDA | c.1329C>T p.G443= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as rs146131049; called by muse, mutect2, varscan2
- HELQ | c.175C>T p.L59= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV99788040; called by muse, mutect2, varscan2
- IKZF1 | c.1509C>T p.Y503= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100498655, COSV58785092; called by muse, mutect2, varscan2
- MYH4 | c.5424G>A p.A1808= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs141762664; called by muse, mutect2, varscan2
- PCDHA7 | c.1479G>A p.S493= | Silent (SNP) | VAF 16/190 reads (8%) | catalogued as COSV65347730; called by muse, mutect2
- PCDHB15 | c.618C>T p.A206= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs1554291860, COSV99179124; called by muse, mutect2, varscan2
- PIGS | c.786C>T p.L262= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs774369852, COSV99257186; called by muse, mutect2, varscan2
- POU4F2 | c.552G>A p.P184= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs936030800, COSV99850742; called by muse, mutect2, varscan2
- SHC2 | c.1194C>T p.Y398= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as rs771419112, COSV99199107; called by muse, mutect2, varscan2
- SLC6A6 | c.1824C>T p.L608= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs1423397444, COSV56119543; called by muse, mutect2, varscan2
- TBX22 | c.462C>T p.Y154= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs1160653048, COSV64785764, COSV64788535; called by muse, mutect2, varscan2
- TUBB | c.498C>T p.T166= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as COSV58358516; called by muse, mutect2, varscan2
- XK | c.15C>T p.A5= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV101064773; called by muse, mutect2
- DNAH8 | c.-41-4547C>T | Intron (SNP) | VAF 11/44 reads (25%) | catalogued as rs368460226, COSV59492992; called by muse, mutect2, varscan2
- NEK7 | c.198+3186G>A | Intron (SNP) | VAF 23/124 reads (19%) | catalogued as rs1303906314, COSV100954374, COSV66312939; called by muse, mutect2, varscan2
